Somatic mutation profile of tumor specimen TCGA-17-Z023-01A (aliquot TCGA-17-Z023-01A-01W-0746-08) from TCGA case TCGA-17-Z023, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a03808d4-4d3c-4c34-ab2e-705cebc4283d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z023-11A (Solid Tissue Normal), aliquot TCGA-17-Z023-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45afcbe4-e313-459b-b664-543e93eba1f7

The open-access MAF lists 427 somatic variants for this specimen: 336 protein-altering or splice-affecting, 83 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 83, Nonsense Mutation 24, Frame Shift Del 14, Intron 5, Splice Site 5, RNA 2, Frame Shift Ins 1, Splice Region 1, 3'UTR 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | hotspot (GDC flag); catalogued as COSV67959999, COSV67960008, COSV67960140; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747136810; called by muse, mutect2, varscan2
- ADAM28 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1190390417, COSV56100063; called by muse, mutect2, varscan2
- ADAMTS20 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465135398; called by muse, mutect2, varscan2
- ADCY8 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs759387076; called by muse, mutect2, varscan2
- ANKRD12 | c.5110C>G p.Q1704E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs372617819; called by muse, mutect2
- ARHGAP20 | c.995G>T p.R332I | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs762760531; called by muse, mutect2, varscan2
- ARHGEF11 | c.2358A>G p.I786M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1311681093; called by muse, mutect2, varscan2
- ATF2 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | catalogued as rs1033953174; called by muse, mutect2, varscan2
- ATP2B4 | c.3284G>C p.R1095P | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV58174116; called by muse, mutect2
- BRINP2 | c.1695C>A p.H565Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64179790; called by muse, mutect2, varscan2
- BSN | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs1178690762, COSV56524414; called by muse, mutect2, varscan2
- CACNA1B | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs200273878, COSV99499627; called by muse, mutect2, varscan2
- CAND2 | c.1627G>T p.V543L (on ENST00000456430 / NM_001162499.2; = p.V450L on NM_012298.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764432053; called by muse, mutect2
- CCDC191 | c.1019A>C p.H340P | Missense Mutation (SNP) | VAF 90/614 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99878914; called by muse, mutect2, varscan2
- CCT6A | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as rs1237261357; called by muse, mutect2, varscan2
- CDH6 | c.727G>C p.G243R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV54066237; called by muse, mutect2, varscan2
- CDKN2A | c.334del p.R112Vfs*34 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as CM013695, COSV58684425, COSV58709681, COSV58723857; called by mutect2, pindel, varscan2
- CFAP251 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as rs952744418; called by muse, mutect2, varscan2
- CHD4 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); catalogued as rs1420236020; called by muse, mutect2, varscan2
- CNGA3 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99737238; called by muse, mutect2
- CNN1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs748140771, COSV52955266, COSV52956274; called by muse, mutect2, varscan2
- COL11A1 | c.3086C>A p.P1029Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV62173317; called by muse, mutect2, varscan2
- COL1A2 | c.1264A>T p.S422C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs1201866454; called by muse, mutect2, varscan2
- COL9A1 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57878099; called by muse, mutect2
- CRX | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV55758496; called by muse, mutect2
- CSMD3 | c.1645G>T p.G549C (on ENST00000297405 / NM_001363185.1; = p.G445C on NM_052900.3) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99841375; called by muse, mutect2, varscan2
- CTNNA2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.789); catalogued as rs774683181; called by muse, mutect2, varscan2
- CTNNA2 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.443); catalogued as rs1361327745; called by muse, mutect2, varscan2
- CTNND2 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV58921411; called by muse, mutect2, varscan2
- DCAF4L2 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs375835458; called by muse, mutect2, varscan2
- DDX43 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV100946485, COSV64836729; called by muse, mutect2, varscan2
- DGKI | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs1368014774, COSV99937062; called by muse, mutect2, varscan2
- DZIP3 | c.381C>G p.H127Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100847704; called by muse, mutect2
- EPHX1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as rs556212945, COSV55300896; called by muse, mutect2
- FAM160A2 | c.1822G>C p.E608Q (on ENST00000449352 / NM_001098794.2; = p.E622Q on NM_032127.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1293200922; called by muse, mutect2, varscan2
- FAM161A | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.155); catalogued as rs369115510, COSV56765440, COSV56766530; called by muse, mutect2, varscan2
- FRMD4A | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52728107; called by muse, mutect2, varscan2
- FSCN3 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.089); catalogued as COSV56170741; called by muse, mutect2, varscan2
- FURIN | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs753178103, COSV51575105; called by muse, mutect2, varscan2
- GABRG1 | c.1037C>A p.A346E | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1207133292, COSV54950691, COSV54952481; called by muse, mutect2, varscan2
- GIGYF2 | c.2417G>C p.R806P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV101004322; called by muse, mutect2
- GPC5 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs751145252; called by muse, mutect2, varscan2
- GPR149 | c.238A>T p.M80L | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs952589424; called by muse, mutect2
- GRAMD1C | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV100822796; called by muse, mutect2, varscan2
- GRM3 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs1372002096; called by muse, mutect2, varscan2
- GRXCR1 | c.202T>A p.S68T | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs1422937318; called by muse, mutect2, varscan2
- HCN1 | c.627C>A p.D209E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1177307612; called by muse, mutect2, varscan2
- HIVEP3 | c.5665G>A p.A1889T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1286378833, COSV99911918; called by muse, mutect2, varscan2
- HMGCR | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as COSV99843168; called by muse, mutect2, varscan2
- HTR1A | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.625); catalogued as COSV60500804; called by muse, mutect2, varscan2
- HTR1A | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100109369, COSV60502027; called by muse, mutect2, varscan2
- IL10 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745923816; called by muse, mutect2, varscan2
- KEL | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV62334316; called by muse, mutect2, varscan2
- LRP1B | c.13448A>G p.N4483S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1427895631; called by muse, mutect2
- LRP1B | c.8755G>C p.G2919R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV101255411; called by muse, mutect2, varscan2
- LURAP1L | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228371096; called by muse, mutect2, varscan2
- MAGEC2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 233/407 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV56001098; called by muse, mutect2, varscan2
- MAP3K9 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs879195926, COSV67120658, COSV67120692; called by muse, mutect2, varscan2
- MERTK | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV54930380, COSV54937416; called by muse, mutect2, varscan2
- MS4A1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV61942211; called by muse, mutect2, varscan2
- MUC16 | c.2277C>G p.I759M | Missense Mutation (SNP) | VAF 53/607 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV101200077; called by muse, mutect2
- MYG1 | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs768954010; called by muse, mutect2, varscan2
- MYH6 | c.2638G>A p.V880M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62447710; called by muse, mutect2, varscan2
- MYH8 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as rs1456404225; called by muse, mutect2, varscan2
- MYOM2 | c.2372C>A p.A791D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs868235767, COSV50728410; called by muse, mutect2, varscan2
- NALCN | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99218251; called by muse, mutect2, varscan2
- NAV3 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs945164074, COSV57072562; called by muse, mutect2, varscan2
- NCAPG | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV104380379; called by muse, mutect2, varscan2
- NPAP1 | c.2718del p.Q907Sfs*20 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as COSV61505137; called by mutect2, pindel, varscan2
- NPEPPS | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs898532030; called by muse, mutect2
- NPR3 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV54085441; called by muse, mutect2
- NRAP | c.1959G>T p.R653S (on ENST00000359988 / NM_001322945.2; = p.R618S on NM_006175.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63489592; called by muse, mutect2, varscan2
- OR10J5 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs567014593; called by muse, mutect2, varscan2
- OR2G6 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573773; called by muse, mutect2
- OR2G6 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100598315; called by muse, mutect2
- OR2M2 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62899061; called by muse, mutect2, varscan2
- OR51A7 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as COSV100834787; called by muse, mutect2, varscan2
- OR51D1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as rs749655480; called by muse, mutect2, varscan2
- OR9I1 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.212); catalogued as rs143742477; called by muse, mutect2, varscan2
- PDE7A | c.1366A>G p.R456G (on ENST00000401827 / NM_001242318.3; = p.R430G on NM_002603.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1248608097; called by muse, mutect2, varscan2
- PDGFRA | c.149T>G p.F50C | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV99958339; called by muse, mutect2, varscan2
- PDZRN4 | c.2815C>A p.R939S (on ENST00000402685 / NM_001164595.2; = p.R681S on NM_013377.4) | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54192124; called by muse, mutect2, varscan2
- PIK3CG | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.065); catalogued as COSV63247982; called by muse, mutect2, varscan2
- PITX2 | c.704C>A p.P235Q (on ENST00000354925 / NM_001204397.1; = p.P242Q on NM_000325.6) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60740837; called by muse, mutect2, varscan2
- PLA2G12B | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1387565579, COSV65978574; called by muse, mutect2, varscan2
- PLEKHG2 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as rs868184652; called by muse, mutect2, varscan2
- PLPPR4 | c.1704C>G p.N568K | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.035); catalogued as rs1190800164; called by muse, mutect2, varscan2
- PLSCR4 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777971555, COSV61608894; called by muse, mutect2, varscan2
- PLXNA2 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV65444241; called by muse, mutect2
- PROKR1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV58137393; called by muse, mutect2, varscan2
- PRR14 | c.662del p.P221Qfs*60 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1189047748; called by mutect2, pindel
- PSG11 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 44/156 reads (28%) | catalogued as COSV60454947; called by muse, mutect2, varscan2
- RASGRP3 | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377431465; called by muse, mutect2, varscan2
- REG1A | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286751; called by muse, mutect2, varscan2
- ROS1 | c.5547A>G p.I1849M | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs1329285758; called by muse, mutect2, varscan2
- SCN11A | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533830451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3D | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1422880899; called by muse, varscan2
- SEMA5A | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375030638, COSV101228754; called by muse, mutect2, varscan2
- SH3BP4 | c.1593G>T p.L531F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs148242042; called by muse, mutect2, varscan2
- SH3BP5L | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1195137164, COSV63539283; called by muse, mutect2, varscan2
- SLC30A8 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 183/319 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs755057304, COSV69971502; called by muse, mutect2, varscan2
- SLIT1 | c.4379G>T p.R1460L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs545410528, COSV56585870, COSV56590504, COSV56594678; called by muse, mutect2, varscan2
- SNX14 | c.656A>T p.Q219L (on ENST00000314673 / NM_001350535.1; = p.Q175L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99042738; called by muse, mutect2, varscan2
- SORCS1 | c.3264G>T p.A1088= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53861899; called by muse, mutect2
- TAS2R41 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.458); catalogued as COSV68765821; called by muse, mutect2, varscan2
- TBL1XR1 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV70499797, COSV70501455; called by muse, mutect2, varscan2
- TECTA | c.4643A>G p.Y1548C | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50691596; called by muse, mutect2, varscan2
- TENM1 | c.4400C>T p.A1467V | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs1292375601, COSV64439757; called by muse, mutect2, varscan2
- TKTL2 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV54920696; called by muse, mutect2, varscan2
- TMEM132D | c.2587C>A p.Q863K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.035); catalogued as rs1247044081; called by muse, mutect2, varscan2
- TMTC3 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.073); catalogued as COSV99898585; called by muse, mutect2, varscan2
- TNN | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV53433171; called by muse, mutect2, varscan2
- TNS3 | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1188603216; called by muse, mutect2, varscan2
- TUSC3 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV65877700, COSV65883577; called by muse, mutect2, varscan2
- USP9X | c.5704G>A p.D1902N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61075844; called by muse, mutect2, varscan2
- ZNF208 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.347); catalogued as rs1327699779, COSV68109692; called by muse, mutect2, varscan2
- ZNF490 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 21/164 reads (13%) | catalogued as COSV61009278; called by muse, mutect2, varscan2
- ZNF571 | c.1357G>T p.G453* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as COSV60733528; called by muse, mutect2, varscan2
- ZSWIM4 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.042); catalogued as rs866586639, COSV54323403; called by muse, mutect2, varscan2
- ABCB5 | c.2010G>T p.E670D (on ENST00000404938 / NM_001163941.2; = p.E225D on NM_178559.6) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ABCC10 | c.3188G>C p.G1063A (on ENST00000372530 / NM_001198934.2; = p.G1035A on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- ABCC12 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AC126283.2 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACIN1 | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2768A>G p.Y923C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY6 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADGRG3 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AGFG2 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AGL | c.3803G>A p.R1268K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- AKR1C8P | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMER1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER1 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANOS1 | c.1746G>A p.M582I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APLP1 | c.1570C>T p.L524F (on ENST00000221891 / NM_001024807.3; = p.L523F on NM_005166.4) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APOBR | c.2346C>A p.D782E (on ENST00000431282; = p.D791E on NM_018690.4) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2
- ARHGEF15 | c.2446A>G p.R816G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARMCX5 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ATP1A3 | c.511C>A p.Q171K (on ENST00000545399 / NM_001256214.2; = p.Q158K on NM_152296.5) | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATR | c.3598G>C p.V1200L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2
- AZGP1 | c.324C>G p.Y108* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- BAZ1B | c.3842G>T p.R1281L | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BEX2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 62/125 reads (50%) | called by muse, mutect2, varscan2
- BMT2 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- BRCA2 | c.1693_1702del p.A565Hfs*5 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- BRCA2 | c.5882G>C p.S1961T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BRCC3 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- BRWD1 | c.5472C>G p.D1824E | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BSN | c.7609G>T p.D2537Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BUD13 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- C6 | c.1458+1G>A p.X486_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- C6 | c.1090C>A p.H364N | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASP2 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CCDC134 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CCDC83 | c.1156G>C p.E386Q (on ENST00000342404 / NM_001286159.2; = p.E417Q on NM_173556.5) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CCT6B | c.1087_1088del p.I363* | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2*
- CD48 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDC42BPA | c.4420G>C p.D1474H (on ENST00000334218 / NM_001366019.2; = p.D1461H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- CFAP54 | c.5381T>A p.L1794Q | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CGNL1 | c.199_204delinsCA p.T67Hfs*13 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by pindel, varscan2*
- CHRFAM7A | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- CIR1 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CLASP1 | c.2246G>T p.S749I | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNGB1 | c.2689A>G p.M897V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CNST | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTN1 | c.2017C>G p.P673A | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYBG1 | c.2192A>T p.K731M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.8107G>T p.V2703L (on ENST00000520002; = p.V2702L on NM_033225.6) | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CSN3 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CYP27B1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DAB1 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DGKI | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHCR7 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK1 | c.4709G>T p.W1570L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- DOCK1 | c.4753A>T p.K1585* | Nonsense Mutation (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- EEA1 | c.4036A>T p.N1346Y | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EFCAB6 | c.3957G>T p.K1319N | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- EIF4B | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ELAVL1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAVL4 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ELMO1 | c.2168T>C p.V723A | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ESRP1 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ETS1 | c.384T>A p.H128Q | Missense Mutation (SNP) | VAF 40/616 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ETV3L | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EXOC6 | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- FANCM | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- FAP | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP11 | c.253A>T p.I85L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- FLNC | c.5619G>A p.M1873I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- FOXK1 | c.569dup p.R191Pfs*113 | Frame Shift Ins (INS) | VAF 32/285 reads (11%) | called by mutect2, pindel, varscan2
- GCG | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GLIS3 | c.1185_1188del p.R396Ifs*4 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- GNPDA2 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GPR89B | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC5B | c.1079G>C p.S360T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GSG1 | c.271C>A p.Q91K (on ENST00000651961 / NM_001080555.4; = p.Q78K on NM_031289.5) | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.419); called by muse, mutect2
- HIVEP3 | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HOXC5 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HRG | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 48/488 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2
- HSPBP1 | c.989A>T p.Q330L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- HSPG2 | c.5528C>T p.S1843F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HUS1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYDIN | c.4623A>C p.E1541D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IAPP | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGKV2D-30 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ILF3 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- INHBA | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ITGB8 | c.2036G>C p.S679T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC1 | c.1192A>T p.M398L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNMA1 | c.3668A>T p.E1223V (on ENST00000286628 / NM_001161352.2; = p.E1165V on NM_002247.4) | Missense Mutation (SNP) | VAF 31/381 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.131); called by muse, mutect2
- KDM5B | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); called by muse, mutect2
- KIF21A | c.4553A>T p.Y1518F (on ENST00000361418 / NM_001378440.1; = p.Y1505F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIR3DL1 | c.1202T>C p.L401S | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- KRT5 | c.1290C>A p.N430K | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KRTAP5-7 | c.123C>G p.C41W | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, varscan2
- LGR5 | c.317_330del p.P106Hfs*7 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- LILRB2 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- LPCAT1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- LRTM2 | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LTBP1 | c.2280G>T p.K760N (on ENST00000404816 / NM_206943.4; = p.K434N on NM_000627.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- LTBP4 | c.3990_3991insCCA p.D1330_G1331insP (on ENST00000308370 / NM_001042544.1; = p.D1293_G1294insP on NM_003573.2) | In Frame Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- MAGEC1 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MARS1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MC4R | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MFSD8 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MGAM | c.460_476del p.R154Ffs*10 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- MITD1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MTCL1 | c.3804G>T p.W1268C (on ENST00000306329 / NM_001378206.1; = p.W949C on NM_015210.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- MUC16 | c.41803C>A p.L13935M | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC16 | c.12175A>G p.S4059G | Missense Mutation (SNP) | VAF 139/604 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MUC16 | c.8036G>A p.G2679D | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- MUC16 | c.3701G>T p.G1234V | Missense Mutation (SNP) | VAF 73/915 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); called by muse, mutect2
- MYO5A | c.4919G>T p.G1640V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- MYO5A | c.4918G>T p.G1640W | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NAV3 | c.4176_4186del p.T1393Pfs*9 | Frame Shift Del (DEL) | VAF 23/256 reads (9%) | called by mutect2, pindel
- NDUFA9 | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- NFIX | c.726C>G p.N242K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP8 | c.2877-2A>C p.X959_splice | Splice Site (SNP) | VAF 11/99 reads (11%) | called by muse, varscan2
- NRK | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRXN3 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP88 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NVL | c.954T>G p.I318M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR10J3 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 106/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR14I1 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR2B6 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2T11 | c.679T>A p.S227T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR51F2 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR6C75 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- OR8B8 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OSBPL8 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PCDH11Y | c.946A>T p.I316F (on ENST00000400457 / NM_032973.2; = p.I305F on NM_032971.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- PCDHA12 | c.1742T>A p.V581E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PITX2 | c.703C>G p.P235A (on ENST00000354925 / NM_001204397.1; = p.P242A on NM_000325.6) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PKHD1 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2G12A | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PLCH1 | c.2506T>A p.Y836N (on ENST00000340059 / NM_001130960.2; = p.Y848N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLD3 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHG2 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLXNA2 | c.1499A>C p.E500A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- PRAMEF14 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, varscan2
- PREX1 | c.2909C>G p.T970S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRNP | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PRPF38B | c.1164G>C p.R388S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2
- PRUNE2 | c.3475G>T p.E1159* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- PTPN12 | c.1168A>T p.K390* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- PTPRM | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RBM46 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RELN | c.10141G>T p.D3381Y | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMKLA | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RNASE8 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.8005T>C p.W2669R (on ENST00000389232; = p.W2670R on NM_001036.6) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SCN3A | c.5102G>T p.C1701F | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SERPINA3 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SHANK2 | c.3100A>G p.I1034V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SIGLEC9 | c.12_26del p.L5_L9del | In Frame Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- SLC12A1 | c.604T>A p.W202R | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A5 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLC9A4 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLF2 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLFN5 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SMCR8 | c.2782G>C p.D928H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SMG1 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SNX2 | c.1259C>G p.A420G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SOGA3 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SPATA31E1 | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPATA31E1 | c.1972G>T p.G658W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTA1 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ST3GAL6 | c.81T>A p.N27K | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- STAB2 | c.4555del p.E1519Rfs*42 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- STK31 | c.2637+2T>A p.X879_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- SULF2 | c.2294A>C p.E765A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SVEP1 | c.3061G>T p.G1021* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- TAF9 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAFA1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2
- TCTN1 | c.1093C>G p.H365D (on ENST00000551590 / NM_001173975.3; = p.H351D on NM_024549.6) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOB2 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TRANK1 | c.3295G>T p.D1099Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TRIM2 | c.1557C>G p.F519L (on ENST00000437508; = p.F546L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TRPC5 | c.743G>T p.C248F | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM2 | c.1357del p.D453Tfs*4 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- TRPM4 | c.1677G>C p.W559C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRRAP | c.7195A>C p.M2399L (on ENST00000359863 / NM_001244580.1; = p.M2381L on NM_003496.3) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC7A | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTLL1 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TTN | c.102244T>A p.C34082S (on ENST00000591111; = p.C26658S on NM_003319.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.42100A>T p.S14034C (on ENST00000591111; = p.S6610C on NM_003319.4) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- UGT1A10 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- UNC79 | c.2950C>A p.L984M (on ENST00000393151 / NM_001346218.2; = p.L807M on NM_020818.5) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- USH2A | c.7603C>T p.P2535S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- VAV3 | c.1981-1G>A p.X661_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- VCAN | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- WBP2NL | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY3 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR17 | c.2021A>T p.D674V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR64 | c.1365A>C p.E455D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- XIRP2 | c.1279G>T p.G427C (on ENST00000628543; = p.G602C on NM_152381.6) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- XKRX | c.1208A>G p.Q403R | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- XRRA1 | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZADH2 | c.988del p.C330Vfs*37 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZCCHC9 | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- ZFP14 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP82 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- ZIC1 | c.944_945del p.R315Lfs*22 | Frame Shift Del (DEL) | VAF 62/222 reads (28%) | called by pindel, varscan2
- ZNF233 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF248 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF257 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ZNF354B | c.1314T>A p.Y438* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- ZNF507 | c.2842A>G p.T948A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF613 | c.990G>T p.R330S (on ENST00000293471 / NM_001031721.4; = p.R294S on NM_024840.4) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.125); called by muse, varscan2
- ZNF667 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ZNF827 | c.2642G>C p.S881T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AASDH | c.1152T>A p.V384= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- ACTRT1 | c.138G>T p.V46= | Silent (SNP) | VAF 59/102 reads (58%) | called by muse, mutect2, varscan2
- ADAM2 | c.1203G>T p.G401= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55866937; called by muse, mutect2, varscan2
- ADCY4 | c.1641G>A p.Q547= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- AGAP3 | c.375G>C p.G125= (on ENST00000622464; = p.G161= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/275 reads (20%) | called by muse, mutect2, varscan2
- AK5 | c.516C>T p.H172= (on ENST00000354567 / NM_174858.3; = p.H146= on NM_012093.4) | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- ANK2 | c.1233C>T p.I411= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV52149163; called by muse, mutect2, varscan2
- ARSK | c.7C>T p.L3= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- ATG2B | c.2982C>G p.L994= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.2157A>G p.R719= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- BDH1 | c.555G>A p.R185= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- CA8 | c.426G>A p.L142= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs1186261958; called by muse, mutect2, varscan2
- CACNA1B | c.1284G>A p.L428= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs1472767756; called by muse, mutect2, varscan2
- CACNA1C | c.5001G>A p.R1667= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- CALCB | c.333C>A p.T111= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- CDHR3 | c.1737G>C p.L579= | Silent (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- CDK20 | c.115C>A p.R39= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- CHRDL1 | c.747G>A p.K249= (on ENST00000372045; = p.K255= on NM_145234.4) | Silent (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- CLDN23 | c.327C>A p.P109= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs757985542; called by muse, mutect2, varscan2
- DAAM2 | c.1857T>A p.P619= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- DBT | c.735G>A p.P245= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs752454574, COSV64496345; called by muse, mutect2, varscan2
- DNAH5 | c.11796A>G p.P3932= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- DNAI3 | c.525G>A p.T175= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as rs757593463, COSV54001253; called by muse, mutect2
- DNAI4 | c.2463G>C p.L821= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- DNER | c.1803T>C p.N601= | Silent (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- ELAVL4 | c.54C>A p.S18= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- EYA1 | c.1521A>C p.P507= | Silent (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- FRMD4A | c.699G>T p.L233= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- GRIN2B | c.3810G>A p.V1270= | Silent (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- HEXIM1 | c.789G>A p.L263= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- HSPA6 | c.1119T>C p.Y373= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs762570646; called by muse, mutect2, varscan2
- IGKV1-5 | c.342T>C p.N114= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs776141927; called by muse, mutect2, varscan2
- ITGA2B | c.2850G>T p.L950= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- KCNK13 | c.444C>T p.R148= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- KRTAP1-1 | c.420C>A p.P140= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV60397922; called by muse, mutect2, varscan2
- LAMA4 | c.3174C>A p.A1058= (on ENST00000230538 / NM_001105206.3; = p.A1051= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- LIPN | c.1131C>T p.V377= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- LRFN1 | c.24G>T p.S8= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1436693920; called by muse, mutect2, varscan2
- MANEA | c.873C>A p.R291= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- MAP3K19 | c.2046C>T p.N682= | Silent (SNP) | VAF 44/163 reads (27%) | called by muse, mutect2, varscan2
- MAP4K3 | c.2268G>T p.T756= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs185367346; called by muse, mutect2, varscan2
- MMP26 | c.9C>G p.L3= | Silent (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.19791G>A p.V6597= | Silent (SNP) | VAF 129/481 reads (27%) | catalogued as COSV67465630; called by muse, mutect2, varscan2
- MYH11 | c.3930G>A p.V1310= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs369184213; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAALADL2 | c.1425T>G p.R475= | Silent (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- NRROS | c.1263C>G p.L421= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NWD1 | c.654T>G p.A218= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1360397569; called by muse, mutect2, varscan2
- OR4C11 | c.195C>T p.S65= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs1414919940, COSV56354691; called by muse, mutect2, varscan2
- OR4S1 | c.789G>T p.L263= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- OR8D1 | c.825T>C p.S275= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs1444726342; called by muse, mutect2, varscan2
- OR9G4 | c.420C>G p.L140= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as rs1290095860, COSV57248594; called by muse, mutect2, varscan2
- OR9I1 | c.861T>A p.P287= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs1251723994; called by muse, mutect2, varscan2
- PCDHA6 | c.1164G>T p.S388= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs365581, COSV67036506; called by muse, mutect2, varscan2
- PDE8B | c.1731C>A p.G577= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as rs781228712; called by muse, mutect2, varscan2
- PDE9A | c.147G>C p.T49= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- PEX6 | c.1992G>A p.E664= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs267608230, CM100012; called by muse, mutect2, varscan2
- PIP4K2C | c.1020G>T p.R340= | Silent (SNP) | VAF 79/212 reads (37%) | catalogued as rs1565715964; called by muse, mutect2, varscan2
- PKHD1L1 | c.7650C>T p.T2550= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs758602334; called by muse, mutect2, varscan2
- PPFIA2 | c.330A>G p.L110= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1390851256; called by muse, mutect2, varscan2
- PRSS54 | c.549C>A p.V183= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PTGFR | c.840G>T p.L280= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- PTPRD | c.2118C>A p.T706= | Silent (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- RFPL2 | c.183A>G p.K61= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- RYR2 | c.7992G>A p.L2664= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1187713365, COSV100773165; called by muse, mutect2, varscan2
- SCARB2 | c.1176A>G p.L392= | Silent (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- SLC25A13 | c.1947G>T p.G649= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV55704830; called by muse, mutect2, varscan2
- SLCO1B3 | c.1707A>T p.A569= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1369507740; called by muse, mutect2, varscan2
- SMYD1 | c.360G>A p.G120= | Silent (SNP) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- SYT10 | c.1234C>A p.R412= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- SYTL5 | c.231G>T p.R77= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- TAAR1 | c.105G>T p.L35= | Silent (SNP) | VAF 118/257 reads (46%) | catalogued as COSV51588996; called by muse, mutect2, varscan2
- TAAR6 | c.345T>C p.F115= | Silent (SNP) | VAF 79/193 reads (41%) | called by muse, mutect2, varscan2
- TP53 | c.591G>T p.V197= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV52817015, COSV52994800; called by muse, mutect2, varscan2
- TRAV14DV4 | c.315G>A p.G105= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs1219196507; called by muse, mutect2, varscan2
- TTC7A | c.2214G>T p.A738= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- UHRF2 | c.414C>T p.V138= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- USP29 | c.144A>T p.I48= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- USP4 | c.1437G>A p.L479= | Silent (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- WDR44 | c.1410A>C p.S470= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- XIRP2 | c.2196G>T p.G732= (on ENST00000628543; = p.G907= on NM_152381.6) | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- ZNF233 | c.1575C>T p.A525= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- ZNF462 | c.3852C>T p.I1284= | Silent (SNP) | VAF 424/976 reads (43%) | called by muse, mutect2, varscan2
- ZNF808 | c.123G>C p.L41= | Silent (SNP) | VAF 66/396 reads (17%) | called by muse, mutect2, varscan2
- ADAM22 | c.2576+4675T>C | Intron (SNP) | VAF 32/105 reads (30%) | catalogued as rs1462960713; called by muse, mutect2, varscan2
- DIRC1 | n.372G>T | RNA (SNP) | VAF 18/121 reads (15%) | catalogued as COSV57369520; called by muse, mutect2, varscan2
- EPHA6 | c.1895-8872C>A | Intron (SNP) | VAF 18/107 reads (17%) | catalogued as rs367672757; called by muse, mutect2, varscan2
- LMNA | c.357-3802C>T | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- PGM1 | c.247-5932A>T | Intron (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1627G>T | RNA (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.10360+1318A>T | Intron (SNP) | VAF 16/78 reads (21%) | catalogued as rs184293990; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF99 | c.*817C>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as rs367594554; called by muse, mutect2, varscan2
